CCDI case PBCJUB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/90e2a755-60b7-4312-9a0e-231543d7b61e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Superior wall of nasopharynx; Age at diagnosis: 2.6 years (942 days).

Biospecimens (3 samples)
- Sample 0DTFRK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTFRR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTFS0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
